Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QN, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QN-01A (Primary Tumor).

[page 1 of 2]
Macroscopic examination :

Resection weighs 195 g and measuring 13 cm x 11 cm x 6.5 cm. It is adherent to a pulmonary resection measuring 10 cm x 3.5 cm x 3 cm . When cut , the thymus is the seat of a large whitish tumor measuring 8 cm x 10 cm x 7 cm, lobulated , adherent to the lung. No cyst or necrosis macroscopically visible.

Histopathological examination :

All samples taken over the entire surface have the same appearance. The thymic parenchyma still identifiable in the sections B , C and P , is made of a large lobulated tumor architecture. The tumor is in effect separated by septa which are thick and fibrous . It consists of polygonal cells of large size, eosinophilic cytoplasm without squamous architecture and therefore without union bridge. The nuclei, large, central or paracentral , sometimes with a nucleolus but a lack of significant atypia of malignancy. These cells have regularly palisade architecture around many clear spaces .

The lymphocytic component is minimal. In periphery , the fibrous capsule is often thick . However, sometimes the lobules adhere without cleavage plane to adjacent mediastinal structures and particularly adipose tissue and the lung parenchyma.

Immunohistochemical examination :

- positive tumor epithelial cells for cytokeratins 19 , 5/6 , 7 and the AE1 / AE3 .
- Absence expression of cytokeratin 20
- Absence expression of CD5 , CD20 and TTF1 ,
- Ki67 : less than 5%
- intraepithelial lymphocytes : positivity for CD1a , CD4, CD8 , confirming the immature nature of T cells.
- Absence CD5 expression of CD99 and CD117

ICD 03
Thymoma, type B3, malignant 858513
Site: Thymus C37.9
gn 4/2/14

[page 2 of 2]
Conclusion :

Thymoma 10 cm diameter Type B3 .

Frank invasion .

Invasion of mediastinal fat and lung parenchyma stage III

Excision is complete

The samples were reviewed by Dr.

Source: NCI Genomic Data Commons file 1debed25-cc35-49f7-b585-d8187e77592b (TCGA-4V-A9QN.07DD75FD-403E-45F9-8254-4222A981ECC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).